CCDI case PBCHTI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a710d177-dc83-4318-9b33-ea1b649877e6

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,228 days).

Biospecimens (4 samples)
- Sample 0DS9ZY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSA08: Tissue type: Tumor; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DSA1F: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DSP2B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
